Somatic mutation profile of tumor specimen TCGA-E8-A434-01A (aliquot TCGA-E8-A434-01A-11D-A23M-08) from TCGA case TCGA-E8-A434, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 56.1 years (20,492 days).
Specimen TCGA-E8-A434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1add4102-f264-4d6e-8c40-118ef05865bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A434-10A (Blood Derived Normal), aliquot TCGA-E8-A434-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf07c756-aa5e-4cfa-bd48-08becae702bc

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBXW7 | c.1481T>G p.L494* (on ENST00000281708 / NM_001349798.2; = p.L414* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV55914082, COSV99661253; called by muse, mutect2, varscan2
- SDC1 | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99587339; called by muse, mutect2, varscan2
- KIF4B | c.1416G>T p.L472= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV101469415; called by muse, mutect2, varscan2
- MKNK2 | c.1281C>A p.V427= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99170431; called by muse, mutect2, varscan2
- TENT5D | c.738C>A p.G246= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100382996; called by muse, mutect2, varscan2
